Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A1KI, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A1KI-01A (Primary Tumor).

[page 1 of 2]
ICB-0-3
Adenocarcinoma, infiltrating ductal, NOS 8500/3
Site: breast, NOS C50.9 2/10/11 *ju*

Patient:

Surgical Pathology: Additional Info

Surg Path

CLINICAL HISTORY:
Mass right breast.

GROSS EXAMINATION:

A. "Sentinel node hot and blue". Received fresh is a 2 x 1.5 x 1 cm tan lymph node which is bisected and submitted in block A1. A cytokeratin is prospectively ordered.

B. Requisition labeled with the patient's name and history number "right breast tissue: long stitch lateral, short superior, white inferior". Received fresh is a 10 (A-P) x 8.5 (M-L) x 3 (S-I) cm breast biopsy specimen which has been inked as follows: superior-blue, inferior-black, anterior-red and posterior-yellow. Sectioning discloses yellow lobulated adipose tissue and thin strands of fibrous tissue without any distinct masses seen. The fibrous tissue appears more prominent and dense at the margins on the anterior edge. There are several punctate hemorrhages located 1 cm from the nearest red inked margin. Sections are submitted from medial to lateral as per gross diagrams in blocks B1-51.

Dr. /Dr. /slides to Dr.

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

DIAGNOSIS:

A. "SENTINEL NODE" (EXCISIONAL BIOPSY):

NEGATIVE FOR MALIGNANCY IN 1 LYMPH NODE (0/1).
CYTOKERATIN IMMUNOHISTOCHEMICAL STAIN IS NEGATIVE.

B. "RIGHT BREAST TISSUE" (EXCISIONAL BIOPSY):

INVASIVE ADENOCARCINOMA OF THE BREAST.

HISTOLOGIC TYPE: DUCTAL.

NOTTINGHAM COMBINED HISTOLOGIC GRADE: 2 OF 3.

TUBULE FORMATION SCORE: 2

NUCLEAR PLEOMORPHISM SCORE: 2

MITOTIC RATE SCORE: 1

GROSS TUMOR SIZE: NOT GROSSLY APPARENT.

SIZE OF INVASIVE COMPONENT: 1.6 CM.

LYMPHATIC/VASCULAR INVASION: ABSENT.

MULTIFOCAL TUMOR: ABSENT.

IN-SITU CARCINOMA: PRESENT

TYPE OF IN SITU CARCINOMA: SOLID

NUCLEAR GRADE OF IN SITU CARCINOMA: 1

NECROSIS: ABSENT

DCIS EXTENDING OUTSIDE OF INVASIVE TUMOR MASS: ABSENT

SIZE OF IN SITU CARCINOMA: NOT APPLICABLE

STATUS OF NON-NEOPLASTIC BREAST TISSUE: DUCTAL HYPERPLASIA OF THE USUAL TYPE, APOCRINE METAPLASIA AND COLUMNAR CHANGES.

SIZE OF BIOPSY: 10.0 X 8.5 X 3.5 CM.

MICROCALCIFICATIONS: ABSENT.

SURGICAL MARGIN STATUS: CLOSE. INVASIVE CARCINOMA IS LESS THAN 0.5 MM FROM THE SUPERIOR SURGICAL MARGIN.

ESTROGEN/PROGESTERONE RECEPTOR, CELL CYCLE, AND HER2/NEU ANALYSIS:

Primary Tumor/site Discrepancy		☒
II/III/IV Discrepancy		☒
Case is a duplicate	☒	☒
Review/Initial	[Signature]	[Signature]

https:

[page 2 of 2]
PENDING.

PARAFFIN BLOCK NUMBER: B18.

RESULTS WILL BE ISSUED IN SEPARATE REPORT FROM THE IMAGE CYTOMETRY LAB

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D. Pager#

Electronically signed:

CI ADDENDUM 1:

Please see
tests.

for results of supplementary

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D., Ph.D. Pager

Electronically signed:

Source: NCI Genomic Data Commons file 6d55c0f1-53e6-4318-bf7f-2c758ee7b6e4 (TCGA-B6-A1KI.C2711492-0BDD-487E-9C9B-CEF20BBE57C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).